Somatic mutation profile of tumor specimen TCGA-B2-5639-01A (aliquot TCGA-B2-5639-01A-01D-1534-10) from TCGA case TCGA-B2-5639, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 46.7 years (17,045 days).
Specimen TCGA-B2-5639-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c94424a-9107-489a-a515-866077694ea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-5639-10A (Blood Derived Normal), aliquot TCGA-B2-5639-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e542501f-d09e-45b5-8c99-1188743f1426

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 14, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-1G>T p.X155_splice | Splice Site (SNP) | VAF 53/135 reads (39%) | hotspot (GDC flag); catalogued as rs5030817, CS071276, CS941547, CS961706, COSV56542304, COSV56544494, COSV56544554, COSV56553901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP2B1 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1005166885, COSV99250952; called by muse, varscan2
- APBA1 | c.1415T>C p.L472P | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99595602; called by muse, mutect2, varscan2
- AQP4 | c.495A>G p.I165M | Missense Mutation (SNP) | VAF 116/355 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV101270492; called by muse, mutect2, varscan2
- BMF | c.305A>C p.Y102S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99590376; called by muse, mutect2, varscan2
- C9orf64 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs745469947, COSV100123509; called by muse, mutect2, varscan2
- CPLX1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV100408232; called by muse, mutect2, varscan2
- CUL5 | c.1756A>G p.N586D | Missense Mutation (SNP) | VAF 114/367 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV101263642; called by muse, mutect2, varscan2
- DCHS1 | c.5582C>A p.S1861* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100201630; called by muse, mutect2, varscan2
- DNAJC10 | c.2205C>G p.C735W | Missense Mutation (SNP) | VAF 106/383 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99898974; called by muse, mutect2, varscan2
- EPHA4 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.938); catalogued as COSV99915873; called by muse, mutect2, varscan2
- FBXL18 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101212033; called by muse, mutect2, varscan2
- HMOX2 | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776135228, COSV99566379; called by muse, mutect2, varscan2
- HPS5 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834371; called by muse, mutect2, varscan2
- ILKAP | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99610901; called by muse, mutect2, varscan2
- KIAA1109 | c.4530C>G p.F1510L | Missense Mutation (SNP) | VAF 106/379 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV99147450; called by muse, mutect2, varscan2
- KRTAP19-4 | c.243A>T p.L81F | Missense Mutation (SNP) | VAF 112/371 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100478397; called by muse, mutect2, varscan2
- LY9 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99626322; called by muse, mutect2, varscan2
- MAGI2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 165/766 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100833492; called by muse, mutect2, varscan2
- MAP3K4 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 99/310 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100815119; called by muse, mutect2, varscan2
- MED13 | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 162/530 reads (31%) | catalogued as COSV101180823; called by muse, mutect2, varscan2
- MMP17 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100861875, COSV62178488; called by muse, mutect2, varscan2
- MMRN2 | c.2773G>C p.E925Q | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100922516, COSV100922695; called by muse, mutect2, varscan2
- NENF | c.443T>A p.L148H | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100877082; called by muse, mutect2, varscan2
- PES1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.045); catalogued as rs748306040, COSV100073019; called by muse, mutect2, varscan2
- RANBP10 | c.1836T>G p.F612L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100449181; called by muse, mutect2
- RBBP6 | c.3706G>A p.E1236K | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV60503301; called by muse, mutect2, varscan2
- TNKS | c.1864T>A p.L622I | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV100126378; called by muse, mutect2, varscan2
- TNR | c.2453T>A p.M818K | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99688162; called by muse, mutect2, varscan2
- TRERF1 | c.2643T>A p.N881K | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100550128; called by muse, mutect2, varscan2
- TRIM49 | c.1048T>C p.S350P | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100315922; called by muse, mutect2, varscan2
- TRMT1L | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834576; called by muse, mutect2, varscan2
- VPS13B | c.370A>T p.R124* | Nonsense Mutation (SNP) | VAF 87/307 reads (28%) | catalogued as COSV100661085; called by muse, mutect2, varscan2
- ZBTB7B | c.943A>G p.M315V (on ENST00000292176; = p.M349V on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV99420916; called by muse, mutect2, varscan2
- ZNF774 | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100586247; called by muse, mutect2, varscan2
- HLCS | c.479del p.K160Rfs*98 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- HNRNPUL2 | c.539_541del p.G180del | In Frame Del (DEL) | VAF 35/149 reads (23%) | called by mutect2, pindel, varscan2
- MRPL17 | c.182A>C p.D61A | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- PBRM1 | c.2088_2098del p.Y697* | Frame Shift Del (DEL) | VAF 54/144 reads (38%) | called by mutect2, varscan2
- PLEKHH2 | c.3552del p.K1185Rfs*29 | Frame Shift Del (DEL) | VAF 62/228 reads (27%) | called by mutect2, pindel, varscan2
- R3HDM1 | c.2556del p.K852Nfs*16 | Frame Shift Del (DEL) | VAF 83/318 reads (26%) | called by mutect2, pindel, varscan2
- TBC1D1 | c.2803-23_2806del p.X935_splice | Splice Site (DEL) | VAF 30/105 reads (29%) | called by mutect2, pindel, varscan2
- ART1 | c.72C>T p.S24= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV99167132; called by muse, mutect2, varscan2
- ATP13A3 | c.2784C>T p.G928= | Silent (SNP) | VAF 99/292 reads (34%) | catalogued as COSV99756477; called by muse, mutect2, varscan2
- CARMIL1 | c.2976G>A p.R992= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs756828802, COSV100277164; called by muse, mutect2, varscan2
- CREBRF | c.807A>G p.A269= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as rs113149390, COSV99755424; called by muse, mutect2
- ERCC6L | c.765C>T p.L255= | Silent (SNP) | VAF 111/213 reads (52%) | catalogued as COSV100559024; called by muse, mutect2, varscan2
- MED13 | c.1977G>T p.V659= | Silent (SNP) | VAF 161/524 reads (31%) | catalogued as COSV101180825; called by muse, mutect2, varscan2
- NCKAP5L | c.681C>T p.G227= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs757532829, COSV100258462; called by muse, varscan2
- OR1N1 | c.393C>A p.S131= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV100509668; called by muse, mutect2, varscan2
- PANX3 | c.847T>C p.L283= | Silent (SNP) | VAF 77/220 reads (35%) | catalogued as COSV99421310; called by muse, mutect2, varscan2
- PPM1L | c.204G>A p.Q68= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as rs1163416957, COSV101534446; called by muse, mutect2, varscan2
- SPON1 | c.1285C>T p.L429= | Silent (SNP) | VAF 80/426 reads (19%) | catalogued as COSV100115387; called by muse, mutect2, varscan2
- USP2 | c.342T>A p.P114= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99489407; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1098C>A p.A366= | Silent (SNP) | VAF 49/208 reads (24%) | catalogued as COSV60158362; called by muse, mutect2, varscan2
- ZNF773 | c.63T>G p.A21= | Silent (SNP) | VAF 42/354 reads (12%) | catalogued as COSV56588342, COSV99989129; called by muse, mutect2
- NEBL | c.164+25967G>C | Intron (SNP) | VAF 109/351 reads (31%) | catalogued as rs770897508, COSV101008694; called by muse, mutect2, varscan2
